MMRF case MMRF_2293 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/22cbce6e-fcf1-4e47-8566-30280fb87caa

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.5 years (25,369 days); ISS stage: I; Days to last known disease status: 793 days (2.2 years); Days to last follow up: 793 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 298 days; Days to treatment end: 298 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 3.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.34 mg/dL; Immunoglobulin G 2.83 g/L; Immunoglobulin A 37.5 g/L; Immunoglobulin M 0.097 g/L; Beta 2 Microglobulin 3.11 µg/mL; Lactate Dehydrogenase 4.72 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.27 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 103 µmol/L; Calcium 2.48 mmol/L; Albumin 40 g/L; Total Protein 8.4 g/dL; Glucose 4.4 mmol/L; C-Reactive Protein 0.38 mg/dL.
- Day 88: M Protein 0.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 3.12 g/L; Immunoglobulin A 0.703 g/L; Immunoglobulin M 0.165 g/L; Beta 2 Microglobulin 1.93 µg/mL; Lactate Dehydrogenase 3.83 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.37 ×10⁹/L; Absolute Neutrophil 1.63 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 96.4 µmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 5.4 g/dL; Glucose 7.26 mmol/L.
- Day 144 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2 mg/dL; Immunoglobulin G 4.83 g/L; Immunoglobulin A 1.05 g/L; Immunoglobulin M 0.198 g/L; Beta 2 Microglobulin 1.86 µg/mL; Lactate Dehydrogenase 3.62 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.47 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 88.4 µmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 5.4 g/dL; Glucose 4.29 mmol/L.
- Day 257 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Immunoglobulin G 4.41 g/L; Immunoglobulin A 0.543 g/L; Immunoglobulin M 0.303 g/L; Beta 2 Microglobulin 2.16 µg/mL; Lactate Dehydrogenase 4.63 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 24 ×10⁹/L; Absolute Neutrophil 21.7 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 88.4 µmol/L; Calcium 2.2 mmol/L; Albumin 37.8 g/L; Total Protein 5.4 g/dL; Glucose 3.69 mmol/L.
- Day 375 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.14 mg/dL; Immunoglobulin G 3.25 g/L; Immunoglobulin A 0.116 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 3.96 µg/mL; Hemoglobin 7.25 mmol/L; Leukocytes 4.45 ×10⁹/L; Absolute Neutrophil 1.08 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 88.4 µmol/L; Calcium 2.1 mmol/L; Albumin 37 g/L; Total Protein 4.8 g/dL; Glucose 4.18 mmol/L.
- Day 458: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.52 mg/dL; Immunoglobulin G 6.91 g/L; Immunoglobulin A 0.228 g/L; Immunoglobulin M 0.309 g/L; Beta 2 Microglobulin 2.39 µg/mL; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.92 ×10⁹/L; Absolute Neutrophil 2.21 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 87.5 µmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 5.8 g/dL; Glucose 4.18 mmol/L.
- Day 528: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.89 mg/dL; Immunoglobulin G 7.02 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.384 g/L; Beta 2 Microglobulin 3.61 µg/mL; Lactate Dehydrogenase 4.53 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.84 ×10⁹/L; Absolute Neutrophil 2.41 ×10⁹/L; Platelets 103 ×10⁹/L; Creatinine 82.2 µmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 6.2 g/dL; Glucose 4.84 mmol/L.
- Day 605 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL; Immunoglobulin G 8.43 g/L; Immunoglobulin A 0.604 g/L; Immunoglobulin M 1.61 g/L; Beta 2 Microglobulin 2.12 µg/mL; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.74 ×10⁹/L; Absolute Neutrophil 1.94 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 91.1 µmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 4.84 mmol/L.
- Day 703 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 7.21 g/L; Immunoglobulin A 0.586 g/L; Immunoglobulin M 0.927 g/L; Beta 2 Microglobulin 1.92 µg/mL; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 5.48 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 98 ×10⁹/L; Creatinine 82.2 µmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 6.4 g/dL; Glucose 5.06 mmol/L.
- Day 793 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 7.15 g/L; Immunoglobulin A 0.695 g/L; Immunoglobulin M 0.825 g/L; Beta 2 Microglobulin 1.99 µg/mL; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 9.55 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.79 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 91.1 µmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 6.4 g/dL; Glucose 4.73 mmol/L.

Other clinical attributes
- Day 1: Weight: 78 kg; Height: 168 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Multiple Myeloma; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2293_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2293_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
